Gene-level copy-number profile of tumor specimen TCGA-D3-A1Q1-06A from TCGA case TCGA-D3-A1Q1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 80.0 years (29,215 days).
Specimen TCGA-D3-A1Q1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.8305be5c-b497-48a2-bf98-c30a96714eb5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A1Q1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/14c4da96-2741-4322-bb20-3cf2dfeba480

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,713; copy number 2: 20,561; copy number 3: 13,053; copy number 4: 10,060; copy number 5: 10,306; copy number 6: 1,065; copy number 7: 1,493; copy number 8: 424; copy number 9: 109; copy number 10: 16; copy number 11: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A1Q1-06A-21D-A194-01): tumor purity 0.97, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 13,431 genes in 34 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:114,697,627–248,919,946, 2,762 genes, copy number 5–6 (broad region; genes not listed).
- chr2:38,814–5,812,670, 83 genes, copy number 5 (broad region; genes not listed).
- chr2:48,529,925–52,961,452, 40 genes, copy number 5 (within-gene range 4–5): STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1, RPL7P13, SNORA75, NRXN1, AC068725.1, MTCO1P42, AC009234.1, MIR8485, AC007560.1, AC007682.1, AC007402.1, AC007402.2, KNOP1P3, CRYGGP, AC097463.1, CCDC12P1, AC079304.1, ZNF863P, Y_RNA, LINC01867, GGCTP3, AC139712.1, CRTC1P1, FTH1P6, MIR4431, AC010967.1, AC010967.2, AC010967.3.
- chr2:79,025,686–84,292,202, 44 genes, copy number 5: REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1, AC008067.1, AC012355.1, ANKRD11P1, CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3, AC138623.1, LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2.
- chr2:106,697,331–107,748,270, 12 genes, copy number 5: EEF1A1P12, ST6GAL2, ST6GAL2-IT1, AC016994.1, AC005040.2, PPP1R2P5, AC005040.1, LINC01789, AC096669.1, LINC01885, LINC01886, AC064869.1.
- chr2:114,442,299–115,845,780, 1 gene, copy number 5 (within-gene range 4–5): DPP10.
- chr2:115,079,354–117,539,464, 14 genes, copy number 5: AC093610.1, DPP10-AS1, RPSAP23, AC016721.1, AC104408.1, AC062016.1, MTCYBP39, AC062016.2, MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1, AC064856.1.
- chr2:144,666,312–145,262,988, 5 genes, copy number 5 (within-gene range 4–5): TEX41, AC023128.1, AC023128.2, SGCEP1, LINC01966.
- chr2:166,195,185–167,941,180, 11 genes, copy number 5: SCN9A, SCN7A, AC074101.1, XIRP2, AC092601.1, XIRP2-AS1, AC073050.1, RNU7-148P, CTAGE14P, B3GALT1-AS1, B3GALT1.
- chr6:167,607–42,050,357, 1,219 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:70,972–10,239,863, 217 genes, copy number 5 (broad region; genes not listed).
- chr7:10,901,978–159,233,377, 2,793 genes, copy number 5–6 (broad region; genes not listed).
- chr8:15,806,149–18,401,218, 47 genes, copy number 5–7: PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2, AC011586.2, AC011586.1, FGF20, MICU3, AC079193.2, AC079193.1, ZDHHC2, CNOT7, VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1, MIR548V, AC124069.1, RNA5SP256, AC027117.2, AC027117.1, FGL1, AC087273.1, AC087273.2, PCM1, ASAH1, AC124242.1, AC124242.2, AC124242.3, NAT1, MTND4LP26, NATP, AC025062.1, AC025062.3, AC025062.2, NAT2.
- chr8:18,720,905–18,774,918, 2 genes, copy number 5: AC100800.1, RPL35P6.
- chr8:23,702,451–30,572,256, 145 genes, copy number 6–8 (broad region; genes not listed).
- chr8:42,849,637–53,540,300, 141 genes, copy number 8 (broad region; genes not listed).
- chr8:53,914,719–145,066,685, 1,421 genes, copy number 6–8 (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 5–9 (broad region; genes not listed).
- chr12:39,626,167–42,070,625, 25 genes, copy number 8 (within-gene range 2–8): C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1, AC015540.1, PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1.
- chr12:42,398,550–43,661,101, 22 genes, copy number 7: RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450, AC068802.1, AC012038.2, AC012038.1, MRPS36P5, LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17.
- chr12:45,444,766–46,373,778, 14 genes, copy number 5–11: AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2.
- chr12:46,384,233–46,652,550, 5 genes, copy number 11 (within-gene range 2–11): AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P.
- chr12:47,960,497–50,167,533, 128 genes, copy number 7 (broad region; genes not listed).
- chr12:50,841,498–51,217,708, 21 genes, copy number 8: RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1.
- chr12:51,590,266–51,852,729, 8 genes, copy number 9: SCN8A, HNRNPA3P10, AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT.
- chr12:52,514,575–52,618,559, 6 genes, copy number 8: KRT5, KRT71, KRT74, KRT72, KRT73-AS1, KRT73.
- chr12:57,089,043–61,232,937, 90 genes, copy number 6–11 (broad region; genes not listed).
- chr12:64,186,316–69,224,242, 119 genes, copy number 5–6 (broad region; genes not listed).
- chr12:71,938,845–72,728,844, 7 genes, copy number 5 (within-gene range 4–12): TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr12:80,402,178–80,719,671, 5 genes, copy number 9: PTPRQ, AKIRIN1P1, AC074031.1, MYF6, MYF5.
- chr12:81,868,368–83,661,719, 15 genes, copy number 5–9: AC091515.1, LINC02426, AC011602.1, CCDC59, METTL25, AC089998.3, AC089998.4, AC089998.2, AC089998.1, AC091214.1, TMTC2, RNU6-977P, RPL6P25, AC090680.1, AC093025.1.
- chr17:52,390,515–54,703,430, 15 genes, copy number 5: LINC01982, LINC02089, LINC02876, MTCO1P40, AC034268.2, AC005341.1, AC090079.1, AC090079.2, AC034268.1, RPS2P48, KIF2B, AC023934.1, ISCA1P3, AC015943.1, AC005951.1.
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 5 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
